Gene-level copy-number profile of tumor specimen C3N-03456-01 from CPTAC case C3N-03456, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 64.7 years (23,616 days).
Specimen C3N-03456-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b4690f6c-a857-48e5-a04e-6d4e8a49bbe3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03456-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,742 have no estimate.
https://portal.gdc.cancer.gov/files/b39b573e-5ce5-4668-bda3-0c1ccd545f38

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 528; copy number 1: 1,067; copy number 2: 22,686; copy number 3: 28,568; copy number 4: 4,033; copy number 5: 1,098; copy number 6: 282; copy number 7: 247; copy number 8: 146; copy number 9: 52; copy number 10: 61; copy number 12: 2; copy number 16: 41; copy number 17: 11; copy number 18: 2; copy number 19: 3; copy number 24: 1; copy number 27: 6; copy number 28: 1; copy number 36: 46.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr6:119,057,880–119,069,143, 2 genes (within-gene range 0–3): Y_RNA, MIR548B.
- chr8:7,170,550–7,170,741, 1 gene: SNRPCP15.
- chr8:8,059,572–8,199,973, 1 gene (within-gene range 0–2): AC105233.4.
- chr8:8,154,308–8,226,614, 3 genes: ENPP7P1, FAM85B, AC068020.1.
- chr9:22,046,758–22,046,901, 1 gene (within-gene range 0–2): AL354709.1.
- chr9:39,886,861–39,892,895, 3 genes: RN7SL763P, SNORA70, CR769767.1.
- chr18:51,158,282–51,159,383, 1 gene: SRSF10P1.
- chr21:9,068,361–9,129,752, 3 genes: TEKT4P2, SOWAHCP2, CR392039.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 619 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,350,934–38,516,520, 41 genes, copy number 16: LINC01137, ZC3H12A, MIR6732, MEAF6, MIR5581, SNIP1, FTH1P1, AL034379.1, DNALI1, GNL2, RSPO1, C1orf109, CDCA8, EPHA10, Y_RNA, ACTN4P2, AL929472.1, MANEAL, AL929472.3, YRDC, C1orf122, MTF1, AL929472.4, AL929472.2, INPP5B, SNORA63, RNU6-584P, Metazoa_SRP, SF3A3, RNU6-510P, FHL3, UTP11, POU3F1, MIR3659HG, AL139158.1, MIR3659, AL390839.2, LINC01343, AL513479.1, RNU6-753P, LINC01685.
- chr1:40,531,573–44,991,834, 156 genes, copy number 8–10 (broad region; genes not listed).
- chr5:9,546,200–9,903,852, 8 genes, copy number 8 (within-gene range 4–8): SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221.
- chr11:56,159,394–56,642,471, 41 genes, copy number 7–10: OR8K5, OR5J7P, OR5J2, OR8V1P, AC022882.1, OR8J2, OR5T2, OR5T3, OR5T1, OR8H1, OR8I1P, OR8K3, FAM8A2P, OR8K2P, OR8K1, OR8J1, RPL5P29, OR8U1, OR8L1P, OR5AL2P, OR5AL1, OR5R1, OR5M4P, AP002512.3, OR5M9, OR5M3, OR5M2P, OR5M8, AP002512.1, OR5M7P, AP002512.2, OR5M6P, OR5M5P, OR5M11, OR5M10, OR5M13P, OR5M1, OR5AM1P, OR5M12P, OR5AP1P, OR5AP2.
- chr11:64,531,044–67,716,005, 220 genes, copy number 7 (broad region; genes not listed).
- chr11:69,641,156–71,252,577, 37 genes, copy number 7–28: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr11:101,890,674–104,164,379, 53 genes, copy number 12–36: ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1.
- chr13:72,782,133–73,016,461, 1 gene, copy number 9 (within-gene range 2–9): PIBF1.
- chr13:73,036,401–73,995,056, 11 genes, copy number 9 (within-gene range 6–9): PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12.
- chr13:73,844,683–74,565,445, 9 genes, copy number 9: AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347.
- chr13:75,109,587–75,935,132, 16 genes, copy number 8: RNU6-38P, SSR1P2, CTAGE11P, LINC01078, TBC1D4, AL139230.1, COMMD6, UCHL3, AL137782.1, LMO7-AS1, LMO7, AL137244.1, FAM204CP, LMO7DN, LMO7DN-IT1, LINC00561.
- chr13:76,880,175–77,129,589, 9 genes, copy number 9 (within-gene range 6–9): KCTD12, AC000403.1, BTF3P11, ACOD1, RPL7P44, DHX9P1, CLN5, AC001226.2, FBXL3.
- chr13:77,027,944–77,028,482, 1 gene, copy number 9: AC001226.1.
- chr13:77,080,511–77,081,190, 1 gene, copy number 9 (within-gene range 6–9): MYCBP2-AS2.
- chr16:32,475,051–32,478,250, 1 gene, copy number 17: ABCD1P3.
- chr18:25,818,234–26,438,041, 13 genes, copy number 9: RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543.
- chr21:8,603,547–8,603,984, 1 gene, copy number 9: RPSAP68.

Autosomal genes at a single copy (total copy number 1): 588. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
